Somatic mutation profile of tumor specimen C3L-02707-71 (aliquot CPT0189850007) from CPTAC case C3L-02707, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.2 years (21,250 days).
Specimen C3L-02707-71: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1cbc500-7e8d-4b9e-a50b-19cae4ab7fd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02707-31 (Blood Derived Normal), aliquot CPT0190680002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c118141-d710-414e-90f8-882690074204

The open-access MAF lists 62 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 11, Intron 5, Nonsense Mutation 4, Frame Shift Del 3, 3'UTR 2, RNA 2, In Frame Del 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 29/50 reads (58%) | hotspot (GDC flag); catalogued as rs121909231, CM971278, COSV64288687, COSV64297951; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.55810C>T p.R18604* (on ENST00000591111; = p.R11180* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 39/133 reads (29%) | catalogued as rs1057522256, COSV100593106, COSV60332406; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTN4 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 103/428 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as rs147553733; called by muse, mutect2, varscan2
- BHMT2 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 86/259 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.043); catalogued as rs139123468; called by muse, mutect2, varscan2
- CD163 | c.3289C>T p.R1097W | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs756953570, COSV100775849; called by muse, mutect2, varscan2
- CLEC17A | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 54/226 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs777637590, COSV60427097; called by muse, mutect2, varscan2
- CNTN5 | c.1665del p.N555Kfs*9 | Frame Shift Del (DEL) | VAF 36/149 reads (24%) | catalogued as COSV54293098; called by mutect2, pindel, varscan2
- COL6A6 | c.2156G>A p.R719Q | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756106307, COSV62016664, COSV62040144; called by muse, mutect2, varscan2
- DNAH14 | c.7447C>T p.R2483* (on ENST00000445597; = p.R3136* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 38/148 reads (26%) | catalogued as rs554324373; called by muse, mutect2, varscan2
- GNAT3 | c.818T>C p.I273T | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as rs770717261; called by muse, mutect2, varscan2
- GRM8 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs61737178, COSV100282191; called by muse, mutect2, varscan2
- KIF23 | c.1838G>A p.R613K | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.093); catalogued as rs757920297; called by muse, mutect2, varscan2
- LGALS9 | c.701G>C p.G234A (on ENST00000395473 / NM_009587.3; = p.G202A on NM_002308.4) | Missense Mutation (SNP) | VAF 101/311 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56349900; called by muse, mutect2, varscan2
- MAP2K7 | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 93/344 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755099146, COSV101208977, COSV67607952, COSV67609638; called by muse, mutect2, varscan2
- MMUT | c.1532G>T p.R511L | Missense Mutation (SNP) | VAF 82/236 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.757); catalogued as COSV99222542; called by muse, mutect2, varscan2
- OR10T2 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 92/311 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs371572112; called by muse, mutect2, varscan2
- PCLO | c.5301G>T p.L1767F | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61679816; called by muse, mutect2, varscan2
- RALGAPA2 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.163); catalogued as rs781680114, COSV52496419; called by muse, mutect2, varscan2
- RTL3 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); catalogued as rs148985625, COSV58183919; called by muse, mutect2, varscan2
- SCN11A | c.2944C>T p.R982* | Nonsense Mutation (SNP) | VAF 29/80 reads (36%) | catalogued as rs145290679, COSV56569403; called by muse, mutect2, varscan2
- SIRPD | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 113/388 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as rs139039354, COSV67547239; called by muse, mutect2, varscan2
- TLL1 | c.1378G>A p.A460T | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs772090014; called by muse, mutect2, varscan2
- TRAV14DV4 | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 74/255 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.668); catalogued as rs759856867; called by muse, mutect2
- TTLL9 | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 67/299 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs770951589, COSV60595004; called by muse, mutect2, varscan2
- ADAMTS19 | c.3251A>T p.E1084V | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ADAMTS20 | c.1280A>G p.Y427C | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AGAP9 | c.1031G>C p.W344S | Missense Mutation (SNP) | VAF 137/538 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- CDC42BPB | c.3685C>G p.P1229A | Missense Mutation (SNP) | VAF 128/384 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DENND1C | c.1879T>A p.S627T | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); called by muse, mutect2
- FSIP2 | c.784C>A p.L262I | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRID2 | c.1161T>G p.F387L | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PRC1 | c.1639_1641del p.E547del | In Frame Del (DEL) | VAF 33/100 reads (33%) | called by mutect2, pindel, varscan2
- RAB6A | c.274_276del p.V92del | In Frame Del (DEL) | VAF 23/64 reads (36%) | called by pindel, varscan2
- RAD50 | c.3605G>A p.S1202N | Missense Mutation (SNP) | VAF 116/338 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RGL2 | c.1286T>C p.V429A | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SF3B2 | c.2440C>T p.R814W | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SPAG1 | c.2341del p.A781Lfs*20 | Frame Shift Del (DEL) | VAF 38/115 reads (33%) | called by mutect2, pindel, varscan2
- TSPY1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 95/863 reads (11%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- ZC3H14 | c.1279+1G>A p.X427_splice | Splice Site (SNP) | VAF 56/196 reads (29%) | called by muse, mutect2, varscan2
- ZNF345 | c.1416_1417del p.H472Qfs*5 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | called by mutect2, pindel
- ZNF407 | c.3816A>C p.R1272S | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ABCD1 | c.1743C>T p.D581= | Silent (SNP) | VAF 170/225 reads (76%) | catalogued as rs782026057; ClinVar: likely benign; called by muse, mutect2, varscan2
- DGKI | c.2115C>T p.S705= | Silent (SNP) | VAF 83/492 reads (17%) | catalogued as COSV99934690; called by muse, mutect2, varscan2
- DHX34 | c.903G>A p.T301= | Silent (SNP) | VAF 146/594 reads (25%) | catalogued as rs1228030450; called by muse, mutect2, varscan2
- DTX3 | c.229C>T p.L77= | Silent (SNP) | VAF 4497/4625 reads (97%) | called by muse, mutect2, varscan2
- HECW1 | c.2313C>T p.D771= | Silent (SNP) | VAF 76/289 reads (26%) | catalogued as rs532202982, COSV67820610; called by muse, mutect2, varscan2
- HSF2BP | c.340C>T p.L114= | Silent (SNP) | VAF 82/215 reads (38%) | called by muse, mutect2, varscan2
- MYO16 | c.3993C>A p.A1331= | Silent (SNP) | VAF 105/271 reads (39%) | called by muse, mutect2, varscan2
- SERPINB4 | c.516G>A p.T172= | Silent (SNP) | VAF 57/205 reads (28%) | catalogued as rs756123662, COSV100345630, COSV61985282; called by muse, mutect2, varscan2
- TSHZ2 | c.1293G>A p.S431= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs749447914, COSV61589070; called by muse, mutect2, varscan2
- VSIG10L | c.246T>C p.P82= | Silent (SNP) | VAF 46/145 reads (32%) | called by muse, mutect2, varscan2
- ZNF181 | c.120G>C p.L40= | Silent (SNP) | VAF 35/145 reads (24%) | catalogued as rs1432720766; called by muse, mutect2, varscan2
- AGAP12P | n.1032G>C | RNA (SNP) | VAF 25/40 reads (63%) | called by mutect2, varscan2
- EPCAM | c.76+163C>T | Intron (SNP) | VAF 131/336 reads (39%) | catalogued as rs1413438357; called by muse, mutect2, varscan2
- ERVV-1 | chr19:53010208 G>A | 5'Flank (SNP) | VAF 31/128 reads (24%) | catalogued as rs1037532368; called by muse, mutect2, varscan2
- HERC2P3 | n.863T>A | RNA (SNP) | VAF 83/246 reads (34%) | called by muse, mutect2, varscan2
- PEG10 | c.*568C>A | 3'UTR (SNP) | VAF 19/163 reads (12%) | called by muse, mutect2, varscan2
- SERPINA1 | c.1065+34G>T | Intron (SNP) | VAF 79/239 reads (33%) | catalogued as COSV100872168; called by muse, mutect2, varscan2
- SETD9 | c.98+652dup | Intron (INS) | VAF 39/170 reads (23%) | called by mutect2, pindel, varscan2
- SPOCK3 | c.245-10816A>T | Intron (SNP) | VAF 48/113 reads (42%) | called by muse, mutect2, varscan2
- TOP3A | c.*3005G>A | 3'UTR (SNP) | VAF 18/93 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.10360+1134C>T | Intron (SNP) | VAF 19/37 reads (51%) | catalogued as rs727505183, COSV100610500; ClinVar: likely benign; called by muse, mutect2, varscan2
